Somatic mutation profile of tumor specimen TCGA-A6-5659-01A (aliquot TCGA-A6-5659-01A-01D-1650-10) from TCGA case TCGA-A6-5659, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage I; Age at diagnosis: 82.2 years (30,028 days).
Specimen TCGA-A6-5659-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e57b8c74-0405-4185-9eaa-26dce86b2423.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-5659-10A (Blood Derived Normal), aliquot TCGA-A6-5659-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30aa0889-edbc-4e0e-83cc-9a27b93436b4

The open-access MAF lists 205 somatic variants for this specimen: 156 protein-altering or splice-affecting, 45 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 136, Silent 45, Nonsense Mutation 12, Frame Shift Del 3, Intron 3, In Frame Del 2, Splice Region 1, Frame Shift Ins 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2097G>A p.W699* | Nonsense Mutation (SNP) | VAF 84/116 reads (72%) | catalogued as rs1060503282, CM950072, COSV57342069; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 123/288 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 93/187 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28937318, CM020301, CM100648, COSV61123792; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 27/29 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1276A>G p.T426A | Missense Mutation (SNP) | VAF 198/231 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs772861392, COSV52706497; called by muse, mutect2, varscan2
- ABCA2 | c.3227C>T p.S1076L (on ENST00000614293; = p.S1046L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs369448216; called by muse, mutect2, varscan2
- ACOX3 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs756175928, COSV62711951; called by muse, mutect2, varscan2
- ADCY2 | c.2671G>T p.A891S | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs972996270, COSV57871790; called by muse, mutect2, varscan2
- ADCY8 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV53895915, COSV53906214; called by muse, mutect2, varscan2
- ALDH8A1 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781744419, COSV55641768; called by muse, mutect2, varscan2
- ARPP21 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs535145550, COSV51792286, COSV51800995; called by muse, varscan2
- ASIC5 | c.1363G>T p.A455S | Missense Mutation (SNP) | VAF 87/424 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV73332711; called by muse, mutect2, varscan2
- ASMT | c.721C>A p.P241T (on ENST00000381229; = p.P269T on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 163/823 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.529); catalogued as rs775384287, COSV67109842; called by muse, mutect2, varscan2
- ATG9B | c.2149C>T p.L717F | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV52489583; called by muse, mutect2, varscan2
- ATXN3L | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 38/520 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762941993, COSV101019396; called by muse, mutect2
- BAIAP2 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1048795319, COSV58335272; called by muse, mutect2, varscan2
- CACNA2D3 | c.730C>T p.R244* | Nonsense Mutation (SNP) | VAF 37/92 reads (40%) | catalogued as rs1417940298, COSV55537866; called by muse, mutect2, varscan2
- CANT1 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV56605509; called by muse, mutect2, varscan2
- CAV3 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs116840777, CM010790, COSV57478483; ClinVar: uncertain significance; called by muse, mutect2
- CCDC14 | c.1855C>T p.R619C (on ENST00000488653; = p.R571C on NM_022757.5) | Missense Mutation (SNP) | VAF 169/332 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs374105030, COSV59944734; called by muse, mutect2, varscan2
- CCT8L2 | c.548T>C p.L183P | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100743053, COSV63462385; called by muse, mutect2
- CD109 | c.614C>A p.S205Y | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV54649255; called by muse, mutect2, varscan2
- CDH10 | c.1456G>T p.A486S | Missense Mutation (SNP) | VAF 61/379 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as COSV100051511; called by muse, mutect2, varscan2
- CDK12 | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101420452; called by muse, mutect2, varscan2
- CHRD | c.1527C>A p.D509E | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.216); catalogued as COSV52607821; called by muse, mutect2
- CHRNA3 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 55/80 reads (69%) | SIFT tolerated (0.56); PolyPhen benign (0.022); catalogued as rs777301381, COSV58776252; called by muse, mutect2, varscan2
- CHST2 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58885500; called by muse, mutect2, varscan2
- CHUK | c.1438T>G p.L480V | Missense Mutation (SNP) | VAF 151/334 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV64917854; called by muse, mutect2, varscan2
- CLK2 | c.284A>G p.Y95C | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.253); catalogued as rs779725189, COSV100751879; called by muse, mutect2, varscan2
- CLSTN2 | c.2122C>A p.P708T | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.631); catalogued as COSV101515721; called by muse, mutect2, varscan2
- CNTN4 | c.2192G>A p.R731Q | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs761965189, COSV61872783; called by muse, mutect2, varscan2
- COL6A6 | c.4808G>C p.G1603A | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62024755; called by muse, mutect2, varscan2
- CREB3L4 | c.636G>A p.K212= | Splice Region (SNP) | VAF 28/49 reads (57%) | catalogued as COSV55132094; called by muse, mutect2, varscan2
- CSMD3 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV52176756; called by muse, mutect2, varscan2
- CUBN | c.6793G>T p.D2265Y | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV64715397; called by muse, mutect2, varscan2
- CWF19L2 | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 152/438 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV56512380; called by muse, mutect2, varscan2
- DHX8 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52253304; called by muse, mutect2, varscan2
- DISC1 | c.1808C>T p.T603M | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as rs148111679, CM080195, COSV54407026; called by muse, mutect2, varscan2
- DKK2 | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 86/132 reads (65%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1172140233, COSV53397427; called by mutect2, varscan2
- DLG2 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 322/684 reads (47%) | SIFT tolerated (0.74); PolyPhen benign (0.025); catalogued as rs776496218, COSV65839639; called by muse, mutect2, varscan2
- DLGAP2 | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as rs371264718; called by muse, mutect2, varscan2
- DLGAP2 | c.2890G>A p.D964N | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs545242845, COSV70098004; called by muse, mutect2, varscan2
- DMD | c.5524A>G p.R1842G | Missense Mutation (SNP) | VAF 30/1032 reads (3%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100819750; called by muse, mutect2
- DNAI3 | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 43/345 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as rs747622337, COSV54001312; called by muse, mutect2, varscan2
- EP300 | c.1282+1G>A p.X428_splice | Splice Site (SNP) | VAF 56/95 reads (59%) | catalogued as COSV54331805; called by muse, mutect2, varscan2
- EPG5 | c.4909C>T p.L1637F | Missense Mutation (SNP) | VAF 85/127 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV56349521; called by muse, mutect2, varscan2
- FAM120AOS | c.436T>A p.C146S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); catalogued as COSV52904762; called by muse, mutect2, varscan2
- FAM133A | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 333/364 reads (91%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.295); catalogued as COSV59075224; called by muse, mutect2, varscan2
- FAM47B | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 223/237 reads (94%) | SIFT tolerated (0.05); PolyPhen benign (0.25); catalogued as COSV61453842, COSV61456163; called by muse, mutect2, varscan2
- FANCA | c.1095G>T p.M365I | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV66881578; called by muse, mutect2, varscan2
- FAT3 | c.1184T>A p.V395D | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53108329; called by muse, mutect2
- FAT3 | c.6664A>T p.I2222F | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV53108351; called by muse, mutect2, varscan2
- FAT3 | c.7388C>T p.P2463L | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV53108376, COSV53177747; called by muse, mutect2, varscan2
- FFAR1 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50052516; called by muse, mutect2, varscan2
- FHOD1 | c.2783G>A p.R928H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs781200583, COSV50760743; called by muse, mutect2
- FRA10AC1 | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 85/173 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.78); catalogued as COSV63271963; called by muse, mutect2, varscan2
- FREM1 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs780511700, COSV66530629; called by muse, mutect2, varscan2
- GDAP1L1 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 116/227 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs779006217, COSV61157121; called by muse, mutect2, varscan2
- GIMAP5 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.146); catalogued as rs752298821, COSV57529982; called by muse, mutect2, varscan2
- GOT1 | c.1172G>A p.S391N | Missense Mutation (SNP) | VAF 147/305 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV63201601; called by muse, mutect2, varscan2
- HEXIM2 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs773017611, COSV56236383; called by muse, mutect2, varscan2
- HYDIN | c.7562C>T p.T2521M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as rs74861733, COSV59249904; called by mutect2, varscan2
- IKZF1 | c.676T>A p.Y226N | Missense Mutation (SNP) | VAF 72/242 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as COSV100498396; called by muse, varscan2
- INPP5B | c.1106A>G p.N369S (on ENST00000373023; = p.N289S on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs757163667, COSV65960823; called by muse, mutect2, varscan2
- IQCA1 | c.1936G>T p.V646F | Missense Mutation (SNP) | VAF 104/238 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54501755; called by muse, mutect2, varscan2
- IQSEC1 | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.459); catalogued as rs754235473, COSV56223830; called by muse, mutect2, varscan2
- IRS1 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1243329079, COSV59333284, COSV59336305; called by muse, mutect2, varscan2
- ITPRID1 | c.1868G>A p.S623N | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV60074440; called by muse, mutect2, varscan2
- IVL | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.068); catalogued as COSV64216203; called by muse, mutect2, varscan2
- KCNA1 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as COSV66836436; called by muse, mutect2, varscan2
- KCNS2 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54638511; called by muse, mutect2, varscan2
- KDM4A | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV64959528; called by muse, mutect2, varscan2
- KIAA0319L | c.2498C>T p.P833L | Missense Mutation (SNP) | VAF 81/144 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as rs142007809; called by muse, mutect2, varscan2
- KRT39 | c.773C>A p.S258Y | Missense Mutation (SNP) | VAF 114/275 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100842173, COSV62917211; called by muse, mutect2, varscan2
- KRTAP19-5 | c.45C>A p.Y15* | Nonsense Mutation (SNP) | VAF 88/120 reads (73%) | catalogued as COSV100478566; called by muse, varscan2
- LCE2B | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.062); catalogued as COSV100909310; called by muse, mutect2, varscan2
- LRRIQ1 | c.4057A>G p.R1353G | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); catalogued as rs1565854173, COSV101280346; called by muse, mutect2
- MAGEC2 | c.517A>C p.K173Q | Missense Mutation (SNP) | VAF 110/197 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.538); catalogued as COSV55999274; called by muse, mutect2, varscan2
- MAST2 | c.2681G>A p.R894Q | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.349); catalogued as rs753126429, COSV63618108; called by muse, mutect2, varscan2
- MME | c.1781G>T p.G594V | Missense Mutation (SNP) | VAF 103/245 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64707342; called by muse, mutect2, varscan2
- MMP16 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 92/273 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs757895279, COSV54164309; called by muse, mutect2, varscan2
- MUC5B | c.6908C>T p.S2303L | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs772020683, COSV71592011; called by muse, mutect2, varscan2
- MYC | c.437C>T p.S146L (on ENST00000377970; = p.S161L on NM_002467.6) | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV52367052; called by muse, varscan2
- MYO1E | c.1487A>G p.N496S | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as COSV55686943; called by muse, mutect2, varscan2
- MYT1L | c.1880C>T p.T627M | Missense Mutation (SNP) | VAF 120/250 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV101221047, COSV67712558; called by muse, mutect2, varscan2
- NAALADL2 | c.1606A>C p.S536R | Missense Mutation (SNP) | VAF 394/773 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as COSV69156110; called by muse, mutect2, varscan2
- NIPBL | c.6182C>T p.P2061L | Missense Mutation (SNP) | VAF 123/399 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs587783999, COSV56950900; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOTCH1 | c.5944C>T p.R1982W | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764422420, COSV99488070; called by muse, mutect2, varscan2
- NRXN1 | c.2704A>T p.I902F | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV58451495; called by muse, mutect2
- NRXN2 | c.840G>T p.Q280H | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.465); catalogued as COSV55453005; called by muse, mutect2, varscan2
- OGDH | c.2912C>T p.P971L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV56049633; called by muse, mutect2, varscan2
- OR10H2 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100008777; called by muse, mutect2, varscan2
- OR10J5 | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 86/156 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58385563, COSV58386029; called by muse, mutect2, varscan2
- OR2W3 | c.850C>A p.L284I | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.101); catalogued as COSV64456119, COSV64456810; called by muse, mutect2, varscan2
- OR5D18 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 67/138 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs775742265, COSV61737083; called by muse, mutect2, varscan2
- OTOF | c.1021G>A p.V341M | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as rs769432101, COSV55517018; called by muse, mutect2, varscan2
- OTOGL | c.4846C>T p.R1616W (on ENST00000547103; = p.R1607W on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 91/259 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536538111, COSV54016630; called by muse, mutect2, varscan2
- PARP9 | c.368G>A p.W123* | Nonsense Mutation (SNP) | VAF 75/144 reads (52%) | catalogued as COSV64450662; called by muse, mutect2, varscan2
- PCDH17 | c.998C>A p.A333D | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100931657; called by muse, mutect2, varscan2
- PCDHA6 | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.044); catalogued as COSV65341983; called by muse, mutect2, varscan2
- PCDHGA4 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.011); catalogued as rs753002448, COSV53945296; called by muse, mutect2, varscan2
- PCSK7 | c.283C>G p.H95D | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.649); catalogued as COSV100309371; called by muse, mutect2, varscan2
- PDGFRA | c.1715A>G p.Y572C | Missense Mutation (SNP) | VAF 113/169 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57267905; called by muse, mutect2, varscan2
- PLCB3 | c.2507C>T p.P836L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs142407686; called by muse, mutect2, varscan2
- PODN | c.440A>C p.N147T (on ENST00000395871; = p.N99T on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV57013488; called by muse, mutect2, varscan2
- PON3 | c.712G>T p.D238Y | Missense Mutation (SNP) | VAF 99/338 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55699252; called by muse, mutect2, varscan2
- POTEF | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 122/278 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.948); catalogued as rs754169172, COSV62541227; called by muse, mutect2, varscan2
- PPFIA2 | c.2852G>A p.R951H | Missense Mutation (SNP) | VAF 94/165 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61020166; called by muse, mutect2, varscan2
- PPP1R9A | c.1785A>T p.Q595H | Missense Mutation (SNP) | VAF 137/255 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV56892178; called by muse, mutect2, varscan2
- PPP2R2B | c.119C>T p.A40V (on ENST00000394409; = p.A106V on NM_181674.2) | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1554126530, COSV60764226; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRR19 | c.653G>T p.S218I | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV56625255; called by muse, mutect2, varscan2
- PTPRU | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs775440824, COSV60527630; called by muse, mutect2, varscan2
- RADIL | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs1177781598, COSV68199994; called by muse, mutect2, varscan2
- RGS20 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.323); catalogued as rs550487524, COSV52016836; called by muse, mutect2, varscan2
- RPS6KA2 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV99690880; called by muse, mutect2
- RXRB | c.484A>T p.I162F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.551); catalogued as COSV63399705; called by muse, mutect2, varscan2
- SAMD7 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 41/141 reads (29%) | catalogued as COSV59418650; called by muse, mutect2, varscan2
- SCN9A | c.4351T>G p.L1451V (on ENST00000303354; = p.L1440V on NM_002977.3) | Missense Mutation (SNP) | VAF 343/957 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57609404; called by muse, mutect2, varscan2
- SCRN1 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs766147656, COSV54130661; called by muse, mutect2, varscan2
- SLC12A3 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs772187470, CM117099, COSV52634825; called by muse, mutect2, varscan2
- SLC22A2 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 58/119 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs768194904, COSV65266300; called by muse, mutect2, varscan2
- SMARCE1 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 134/321 reads (42%) | catalogued as rs1251821702, COSV52860590; called by muse, mutect2, varscan2
- SNPH | c.396G>T p.Q132H | Missense Mutation (SNP) | VAF 81/157 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67870605; called by muse, mutect2, varscan2
- SORCS1 | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 30/84 reads (36%) | catalogued as COSV53848358, COSV53865482; called by muse, mutect2, varscan2
- SPATA18 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs779355129, COSV54644470; called by muse, mutect2, varscan2
- STON1 | c.1713C>A p.H571Q | Missense Mutation (SNP) | VAF 112/233 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.776); catalogued as rs1262877194, COSV59130422; called by muse, mutect2, varscan2
- TBC1D22B | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.913); catalogued as rs767058134, COSV65142535; called by muse, mutect2, varscan2
- TCHHL1 | c.846G>T p.K282N | Missense Mutation (SNP) | VAF 539/1013 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.22); catalogued as COSV64285688; called by muse, mutect2, varscan2
- TDRD7 | c.3121C>T p.R1041* | Nonsense Mutation (SNP) | VAF 82/152 reads (54%) | catalogued as COSV62429379, COSV62430190; called by muse, mutect2, varscan2
- TMEM132B | c.1940C>T p.T647M | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750179973, COSV54766965; called by muse, mutect2, varscan2
- TNFRSF11A | c.545T>C p.V182A | Missense Mutation (SNP) | VAF 113/152 reads (74%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV54023414; called by muse, mutect2, varscan2
- TOP1 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 36/498 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.271); catalogued as COSV100793824; called by muse, mutect2
- TRIM3 | c.1376C>A p.T459K | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV100624408; called by muse, mutect2, varscan2
- TSPEAR | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 288/367 reads (78%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as rs113059777, COSV59959310, COSV59961665; called by muse, mutect2, varscan2
- TTC9 | c.558C>A p.Y186* | Nonsense Mutation (SNP) | VAF 51/105 reads (49%) | catalogued as COSV56448182; called by muse, mutect2, varscan2
- TTK | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 126/649 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1260979404, COSV57883719; called by muse, mutect2, varscan2
- TUBGCP6 | c.2068C>T p.R690W | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774338870, COSV50541673; called by muse, mutect2, varscan2
- UNC13C | c.5171C>A p.S1724Y | Missense Mutation (SNP) | VAF 103/188 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.48); catalogued as rs1415421209, COSV52871562; called by muse, mutect2, varscan2
- UNC5A | c.1540C>T p.R514W | Missense Mutation (SNP) | VAF 91/105 reads (87%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs749730825, COSV52839070; called by muse, mutect2, varscan2
- VARS1 | c.1303G>A p.G435S | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65155180; called by muse, mutect2, varscan2
- VPS13A | c.1883G>A p.R628H | Missense Mutation (SNP) | VAF 156/357 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62429527; called by muse, mutect2, varscan2
- XKR6 | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 13/16 reads (81%) | catalogued as COSV58656108; called by muse, mutect2, varscan2
- ZDBF2 | c.4241C>T p.S1414F | Missense Mutation (SNP) | VAF 63/172 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65625771; called by muse, mutect2, varscan2
- ZNF408 | c.1565G>A p.R522H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs971021664, COSV61238129; called by muse, mutect2, varscan2
- ZNF530 | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 62/195 reads (32%) | catalogued as rs780728808, COSV60531517; called by muse, mutect2, varscan2
- ZNF607 | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 86/277 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV67696823; called by muse, mutect2, varscan2
- ZNF676 | c.1826G>T p.S609I (on ENST00000650058; = p.S577I on NM_001001411.3) | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.373); catalogued as COSV68093035; called by muse, mutect2, varscan2
- AFDN | c.387_389del p.K129del | In Frame Del (DEL) | VAF 59/145 reads (41%) | called by mutect2, pindel, varscan2
- CC2D1B | c.1549del p.L517Cfs*53 | Frame Shift Del (DEL) | VAF 39/73 reads (53%) | called by mutect2, pindel, varscan2
- IPMK | c.920_921del p.E307Vfs*31 | Frame Shift Del (DEL) | VAF 156/420 reads (37%) | called by pindel, varscan2
- KIAA0232 | c.2353dup p.T785Nfs*3 | Frame Shift Ins (INS) | VAF 30/98 reads (31%) | called by mutect2, varscan2
- MAF | c.997_999del p.E333del | In Frame Del (DEL) | VAF 32/95 reads (34%) | called by mutect2, pindel, varscan2
- MED12L | c.744del p.K248Nfs*5 | Frame Shift Del (DEL) | VAF 131/423 reads (31%) | called by mutect2, pindel, varscan2
- RIMS2 | c.4552G>A p.V1518I (on ENST00000666250 / NM_001348490.2; = p.V1089I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.074); called by muse, mutect2
- WDR74 | c.1115C>T p.T372M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, varscan2
- ALS2 | c.396G>A p.P132= | Silent (SNP) | VAF 86/238 reads (36%) | catalogued as rs374978798; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- AMOTL1 | c.432C>T p.L144= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as rs1328174556, COSV100133792; called by muse, mutect2, varscan2
- CCDC141 | c.3807T>C p.P1269= | Silent (SNP) | VAF 37/115 reads (32%) | catalogued as COSV55373275; called by muse, mutect2
- CD40 | c.273C>A p.V91= | Silent (SNP) | VAF 61/157 reads (39%) | catalogued as COSV64847780; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1005C>T p.T335= (on ENST00000357886 / NM_001365728.1; = p.T321= on NM_016082.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 141/283 reads (50%) | catalogued as COSV59426826; called by muse, mutect2, varscan2
- COL6A3 | c.8637G>A p.T2879= | Silent (SNP) | VAF 85/218 reads (39%) | catalogued as rs1417532835, COSV55088973; called by muse, mutect2, varscan2
- CPAMD8 | c.5496C>T p.D1832= (on ENST00000651564; = p.D1785= on NM_015692.5) | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV99935255; called by muse, mutect2, varscan2
- CPXM2 | c.1692C>T p.D564= | Silent (SNP) | VAF 18/24 reads (75%) | catalogued as rs547897756, COSV53861729; called by muse, mutect2, varscan2
- CYP1A2 | c.1305C>T p.A435= | Silent (SNP) | VAF 30/43 reads (70%) | catalogued as rs745999166, COSV59659682; called by muse, mutect2, varscan2
- DCTPP1 | c.468G>T p.G156= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV100073538; called by muse, mutect2, varscan2
- ESRP2 | c.1350C>T p.S450= (on ENST00000565858 / NM_001365264.1; = p.S440= on NM_024939.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as rs372468822; called by muse, mutect2, varscan2
- FGD3 | c.915G>T p.L305= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV61597243; called by muse, mutect2
- FKBP9 | c.1524C>T p.V508= | Silent (SNP) | VAF 57/233 reads (24%) | catalogued as COSV54230741; called by muse, mutect2, varscan2
- GABRD | c.135C>T p.D45= | Silent (SNP) | VAF 34/60 reads (57%) | catalogued as rs754323369, COSV66080540; ClinVar: likely benign; called by muse, mutect2, varscan2
- GJB5 | c.723C>T p.D241= | Silent (SNP) | VAF 45/139 reads (32%) | catalogued as rs536768375, COSV58356165; called by muse, mutect2, varscan2
- GPR179 | c.1014C>T p.F338= (on ENST00000621958; = p.F337= on NM_001004334.4) | Silent (SNP) | VAF 14/22 reads (64%) | called by muse, varscan2
- GRIA4 | c.2370C>T p.Y790= | Silent (SNP) | VAF 56/157 reads (36%) | catalogued as rs762639803, COSV56895709; called by muse, mutect2, varscan2
- IGHG1 | c.204G>A p.V68= | Silent (SNP) | VAF 92/195 reads (47%) | called by muse, mutect2, varscan2
- LAMP3 | c.738G>A p.L246= | Silent (SNP) | VAF 108/360 reads (30%) | catalogued as COSV55614833, COSV55615604; called by muse, mutect2, varscan2
- LSG1 | c.282C>T p.F94= | Silent (SNP) | VAF 251/538 reads (47%) | catalogued as rs755607314, COSV54570113; called by muse, mutect2, varscan2
- NAT10 | c.1647C>T p.S549= | Silent (SNP) | VAF 40/75 reads (53%) | catalogued as rs577046723, COSV57663760, COSV57666589; called by muse, mutect2, varscan2
- NDUFS6 | c.267C>T p.G89= | Silent (SNP) | VAF 41/70 reads (59%) | catalogued as rs769132703, COSV56876656; called by muse, mutect2, varscan2
- NEXMIF | c.1122G>T p.G374= | Silent (SNP) | VAF 180/197 reads (91%) | catalogued as COSV50030530; called by muse, mutect2, varscan2
- OBSCN | c.7251G>A p.T2417= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as rs371761770, COSV52778616; called by muse, mutect2, varscan2
- OR52E6 | c.480A>T p.P160= | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as COSV61432058; called by muse, mutect2, varscan2
- OR6C74 | c.372C>A p.I124= | Silent (SNP) | VAF 40/126 reads (32%) | catalogued as COSV59606424; called by muse, mutect2, varscan2
- PARP14 | c.1752C>T p.A584= | Silent (SNP) | VAF 44/131 reads (34%) | catalogued as rs951694337, COSV71734663; called by muse, mutect2, varscan2
- PCDHA5 | c.1278G>A p.A426= | Silent (SNP) | VAF 35/56 reads (63%) | catalogued as COSV65352344; called by muse, mutect2, varscan2
- PLEKHA5 | c.1203C>T p.A401= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs150691984; called by muse, mutect2, varscan2
- PRSS12 | c.2157A>C p.R719= | Silent (SNP) | VAF 37/241 reads (15%) | catalogued as COSV99628271; called by muse, mutect2, varscan2
- PSMB10 | c.366G>A p.L122= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as rs772788981, COSV50452772; called by muse, mutect2, varscan2
- RASGRF2 | c.2037G>T p.L679= | Silent (SNP) | VAF 162/209 reads (78%) | catalogued as COSV99429267; called by muse, varscan2
- REG1B | c.399T>C p.N133= | Silent (SNP) | VAF 62/187 reads (33%) | catalogued as COSV59305537; called by muse, mutect2, varscan2
- RYR1 | c.4089G>A p.A1363= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs761793739, COSV62107582; called by muse, mutect2, varscan2
- SELENOO | c.1047C>T p.Y349= | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as rs529648565, COSV101096802; called by muse, mutect2, varscan2
- STAB1 | c.5187C>T p.T1729= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs771251910, COSV58735998; called by muse, mutect2, varscan2
- TFAP2D | c.321C>T p.H107= | Silent (SNP) | VAF 43/85 reads (51%) | catalogued as COSV50415159; called by muse, mutect2, varscan2
- TPR | c.336A>G p.Q112= | Silent (SNP) | VAF 60/261 reads (23%) | catalogued as rs368470841; called by muse, mutect2, varscan2
- TRIM51 | c.1257C>A p.T419= | Silent (SNP) | VAF 54/99 reads (55%) | catalogued as COSV55266395, COSV55267477; called by muse, mutect2, varscan2
- TSPOAP1 | c.2346G>A p.P782= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs746732636, COSV52108360; called by muse, mutect2, varscan2
- TTN | c.4611C>A p.G1537= (on ENST00000591111; = p.G1491= on NM_003319.4) | Silent (SNP) | VAF 41/97 reads (42%) | catalogued as COSV59870835; called by muse, mutect2, varscan2
- WDR24 | c.1143C>T p.I381= (on ENST00000248142; = p.I251= on NM_032259.4) | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as rs749577638, COSV50197522; called by muse, mutect2, varscan2
- XDH | c.2139G>T p.L713= | Silent (SNP) | VAF 120/280 reads (43%) | catalogued as COSV65148593; called by muse, mutect2, varscan2
- ZNF219 | c.1368G>A p.P456= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV53880288; called by muse, mutect2, varscan2
- ZNF493 | c.1548C>T p.L516= | Silent (SNP) | VAF 50/130 reads (38%) | catalogued as rs760617541, COSV62750013; called by muse, varscan2
- GATA3 | chr10:8051081 A>G | 5'Flank (SNP) | VAF 30/68 reads (44%) | catalogued as rs757480024; called by muse, mutect2
- GCNT2 | c.926-34760G>A | Intron (SNP) | VAF 75/173 reads (43%) | catalogued as rs776266980, COSV53942266, COSV99399141; called by muse, mutect2, varscan2
- TTN | c.10361-4501G>T | Intron (SNP) | VAF 115/285 reads (40%) | catalogued as COSV60048958; called by muse, mutect2, varscan2
- UGT1A6 | c.862-23336C>T | Intron (SNP) | VAF 10/36 reads (28%) | catalogued as rs368889261; called by muse, mutect2, varscan2
